Gene-level copy-number profile of tumor specimen HCM-SANG-1336-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-1336-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1336-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e8975e89-bbd1-416f-98f4-8b4b7862c7b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1336-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/0e21713c-f93c-46a5-97cc-091f13299a42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 27,069; copy number 2: 29,635; copy number 3: 2,034; copy number 5: 105.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,590,056–186,765,959, 3 genes: ITGAV, AC017101.1, FAM171B.
- chr3:134,355,347–136,147,894, 19 genes (within-gene range 0–1): AMOTL2, MIR6827, HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1, EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1, AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2.
- chr4:42,281,830–44,841,402, 29 genes: AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1.
- chr5:58,969,038–60,522,120, 9 genes (within-gene range 0–1): PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr14:18,418,775–18,596,310, 5 genes: BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 105 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:55,283,750–56,688,408, 105 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
